Surgical pathology report (de-identified scan), TCGA case TCGA-N8-A4PI, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of North Carolina, specimen TCGA-N8-A4PI-01A (Primary Tumor).

[page 1 of 6]
SURGICAL PATHOLOGY

Case Number :

ICD-0-3
Carcinosarcoma, N/A
8980/3
Site: Endometrium
C54.1
12/14/12 JN

Diagnosis:

- A: Peri-aortic lymph node, right, removal
- No tumor identified in four lymph nodes (0/4)
- B: Peri-aortic lymph node, left, removal
- No tumor identified in four lymph nodes (0/4)
- C: Pelvic nodes, right, removal
- No tumor identified in eleven lymph nodes (0/11)
- D: Pelvic nodes, left, removal
- No tumor identified in ten lymph nodes (0/10) (see comment)
- E: Uterus, cervix, bilateral tubes and ovaries, robotic
hysterectomy and bilateral salpingo-oophorectomy

Location of tumor: endometrium

Histologic type: carcinosarcoma, with heterologous elements
(mixed serous and endometrioid adenocarcinoma and
undifferentiated sarcoma) (see comment)

Histologic grade (FIGO): 3

Extent of invasion: into myometrium

Myometrial invasion: inner half
Depth: 0.9 cm Wall thickness: 2.1 cm Percent: 43% (block
E13)

Serosal involvement: not identified

Lower uterine segment involvement: not identified

Cervical involvement: not identified

Adnexal involvement (see below): not identified

Other sites: N/A

Cervical/vaginal margin and distance: widely negative

Lymphovascular space Invasion: present, rare foci (E7)

[page 2 of 6]
Regional lymph nodes (see other specimens A-D):

Total number involved: 0

Total number examined: 29

Other Pathologic findings:

- Leiomyomata, up to 3.2 cm in greatest dimension
- Adenomyosis
- Vascular calcifications

Tumor estrogen receptor and progesterone receptor immunohistochemistry results:

- ER weak positive (1-2+, 2%)
- PR weak positive (1-2+, 5%)

AJCC Pathologic stage: pT1a pN0

FIGO (2008 classification) Stage grouping: IA

These stages are based on information available at the time of this report, and are subject to change pending additional information and clinical review

Ovary, right, oophorectomy:

- Atrophic
- No tumor seen

Ovary, left, oophorectomy:

- Atrophic
- No tumor seen

Fallopian tube, right, salpingectomy:

- No diagnostic abnormality
- No tumor seen

Fallopian tube, left, salpingectomy:

- No diagnostic abnormality
- No tumor seen

Comment:

Immunostains performed on a representative section of tumor fail to show staining for myogenin. A desmin stain is equivocal with high background staining. These findings lend no support to a rhabdomyosarcomatous component to the tumor.

[page 3 of 6]
An OSCAR pancytokeratin immunostain is performed on block D7, and confirms the diagnosis.

Appropriate internal and/or external positive and negative controls have been evaluated. Some of the immunohistochemical reagents used in this case may be classified as analyte specific reagents (ASR). These were developed and have performance characteristics determined by . These reagents have not been cleared or approved by the US Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA-88) as qualified to perform high complexity clinical laboratory testing.

Clinical History:

.-year-old female with endometrial cancer.

Gross Description:

Received are five appropriately labeled containers.

Container A is additionally labeled "right peri-aortic node." The specimen consists of an unoriented fibrofatty tissue fragment that measures 3 x 2 x 1 cm. They will be palpated for lymph node candidates and submitted per block summary.

Block summary:

A1-A2 - one lymph node candidate, bisected
A3-A4 - one lymph node candidate, bisected
A5 - remainder of fibrofatty tissue,

Container B is additionally labeled "left peri-aortic node." The specimen consists of an unoriented fibrofatty tissue fragment that measures 2 x 1 x 0.5 cm in aggregate. They will be palpated for lymph node candidates and submitted per block summary.

Block summary:

B1 - two lymph node candidates, each bisected (smallest lymph node candidate is inked green prior to bisection)
B2 - one lymph node candidate, bisected

[page 4 of 6]
B3 - remainder of fibrofatty tissue,

Container C is additionally labeled "right pelvic node." The specimen consists of an unoriented fibrofatty tissue fragment that measures 6 x 5 x 2 cm. The tissue will be palpated for lymph node candidates and submitted per block summary.

Block summary:

C1 - one lymph node candidate, bisected
C2 - one lymph node candidate, bisected
C3 - two lymph node candidates
C4 - one lymph node candidate, bisected
C5 - one lymph node candidate, bisected
C6 - one lymph node candidate, bisected
C7-C9 - remainder of fibrofatty tissue,

Container D is additionally labeled "left pelvic node." The specimen consists of an unoriented fibrofatty tissue that measures 5 x 4.5 x 1.5 cm. The specimen will be palpated for lymph node candidates and submitted per block summary.

Block summary:

D1,D2 - one lymph node candidate, bisected
D3 - two lymph node candidates
D4 - one lymph node candidate, bisected
D5 - one lymph node candidate, bisected
D6 - one lymph node candidate, bisected
D7-D8 - remainder of fibrofatty tissue,

Container E:

Adnexa: present
Weight: 213.5 grams
Shape: pear shaped
Dimensions:
height: 12 cm
anterior to posterior width: 8 cm
breadth at fundus: 9 cm
Serosa: tan/pink and unremarkable
Cervix:
length of endocervical canal: 3.2 cm
ectocervix: tan/white with extensive cautery artifact

[page 5 of 6]
endocervix: tan/yellow and trabeculated

Endomyometrium:

length of endometrial cavity: 5.1 cm

width of endometrial cavity at fundus: 4.5 cm

tumor findings:

dimensions: 3.2 x 3.0 x 2.1 cm (final dimension is height above endometrium)

appearance: tan/white, with hemorrhagic areas, papillary in nature and friable

location and extent: involves the fundus, primarily on the posterior aspect, but also extends to the anterior aspect

myometrial invasion: inner one-half thickness of myometrial wall at deepest gross invasion: 1.2 cm

other findings or comments: Multiple intramuscular leiomyoma are seen that range in size from 0.5 to 3.2 cm in diameter. Their cut surfaces are tan/white, whorled and without areas of hemorrhage or necrosis.

Adnexa:

Right ovary:

dimensions: 2.5 x 1.5 x 1.0 cm

external surface: tan/white and cerebriform

cut surface: tan/white and solid

Right fallopian tube:

dimensions: 3 cm, but discontinuance, representing possible prior tubal ligation

other findings: none

Left ovary:

dimensions: 2.5 x 1.2 x 1.2 cm

external surface: tan/white and cerebriform

cut surface: tan/white and solid

Left fallopian tube:

dimensions: 3.2 x 0.2 cm

other findings: this tube is also discontinuance, representing possible prior tubal ligation

Lymph nodes: submitted separately

Other comments: none

Digital photograph taken: no

Tissue submitted for special investigations: yes; Tumor and normal were taken by Tissue Procurement

[page 6 of 6]
Block Summary:

- E1 - anterior cervix
- E2-E3 - anterior lower uterine segment, bisected
- E4-E5 - anterior mid corpus, bisected
- E6-E7 - anterior upper corpus/fundus, bisected (tumor in this section)
- E8 - posterior cervix
- E9-E10 - posterior lower uterine segment, bisected (includes section of fibroid)
- E11-E12 - posterior mid corpus, bisected (contains section of intramuscular leiomyoma)
- E13 - posterior upper corpus/fundus, at area of deepest invasion
- E14 - right tube and ovary
- E15 - left tube and ovary
- E15-E18 - additional representative sections, largest leiomyoma

Diagnostic Discrepancy		
Case Discrepancy		
Review		

12/13/12

12/13/12

Source: NCI Genomic Data Commons file 9a0f6815-7f45-4d9a-ab02-f9371531db4c (TCGA-N8-A4PI.B8CDB9DC-9537-4DA1-A8A5-A6F64708669E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).